Surgical pathology report (de-identified scan), TCGA case TCGA-50-5932, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-5932-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

PRE-OP DIAGNOSIS: Right lung mass.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Right upper lobectomy, mediastinoscopy, lymph node dissection.

[REDACTED]

FINAL DIAGNOSIS:

PART 1: LUNG, RIGHT UPPER LOBE, LOBECTOMY –

- A. WELL DIFFERENTIATED ADENOCARCINOMA WITH BRONCHIOALVEOLAR FEATURES (4.2CM; see comment).
- B. THE NEOPLASM ABUTS THE VISCERAL PLEURA BUT DOES NOT PENETRATE IT.(see comment).
- C. BRONCHIAL, VASCULAR AND PARENCHYMAL MARGINS ARE FREE OF NEOPLASM.
- D. EMPHYSEMATOUS CHANGES OF THE NON NEOPLASTIC LUNG.
- E. ONE OF SEVEN PERIHILAR LYMPH NODES WITH METASTATIC ADENOCARCINOMA; NO EXTERNAL NODE SPREAD IS PRESENT (1/7).
- F. TNM PATHOLOGIC STAGE: T2; N1; MX.
- G. HISTOPATHOLOGIC GRADE = G1.

PART 2: LYMPH NODES, PERIBRONCHIAL, SITE IS NOT SPECIFIED, EXCISION –

- A. FOUR BENIGN LYMPH NODES.
- B. NEGATIVE FOR NEOPLASIA (0/4).

PART 3: LYMPH NODES, PERIAORTIC AND PERIAZYGOS, EXCISION –

- A. SEVEN BENIGN LYMPH NODES.
- B. NEGATIVE FOR NEOPLASIA (0/7).
- [REDACTED]

COMMENT:

Special stains performed on a section of the neoplasm showed neoplastic cells strongly positive for cytokeratin 7 and negative cytokeratin 20 and thyroid transcription factor(TTF (–) probably due to technical problems). Special stain for mucin (PAS with and without diastase) were positive for intracellular mucin. The histologic features and the pattern of immunostaining is compatible with a primary adenocarcinoma (mucinous BAC) of the lung. Elastic stain showed no invasion of the elastic layer of the visceral pleura.

[page 2 of 2]
SYNOPTIC – PRIMARY LUNG TUMORS

- A. Location: 1
1. RUL
2. RML
3. RLL
4. LLL
5. LUL
6. Bronchus intermedius
- B. Procedure: 2
1. Wedge/Segmental
2. Lobectomy
3. Bilobectomy
4. Pneumonectomy
- C. Size of tumor (maximum dimension): 4.2 cm.
- D. Satellite nodules: 2
1. yes
2. No
- D1. If yes, Where: #
1. Same lobe
2. Ipsilateral lobes
3. Central lobe
- E. Type: 3
1. Invasive squamous carcinoma
2. Basaloid squamous carcinoma
3. Invasive adenocarcinoma
4. Bronchioloalveolar carcinoma, nonmucinous type
5. Bronchioloalveolar carcinoma, mucinous type
6. Large cell carcinoma
7. Clear cell carcinoma
8. Giant cell carcinoma
9. Sarcomatoid carcinoma
10. Blastoma
11. Fetal type adenocarcinoma
12. Small cell carcinoma
13. Carcinoid
14. Atypical carcinoid
15. Sarcoma
16. Adenosquamous carcinoma
17. Mixed non-small cell carcinoma, NOS
18. Carcinosarcoma
19. Other
- F. Architectural grade: 1
1. well
2. moderate
3. poor/undifferentiated
- G. Nuclear grade: 1
1. Low
2. Intermediate
3. High
- H. Central vs. peripheral origin: 1
1. yes
2. no
- I. Visceral pleural invasion through elastica: 2
1. yes
2. no
- J. Parietal pleural invasion: 2
1. yes
2. no
- K. Chest wall invasion (into skeletal muscle or soft tissue): 2
1. yes
2. no
- L. Angiolymphatic invasion: 2
1. yes
2. no
- M. Necrosis: 1
1. ≤50%
2. >50%
- N. Surgical margins involved: 2
1. yes
2. no
- O. Inflammatory (desmoplastic) reaction: 1
1. mild
2. moderate
3. severe
- P. Hilar lymph node involvement (N1 nodes): 1
1. yes
2. no
- Q. If hilar lymph nodes involved, number of positive lymph nodes: 1/7
- R. Total number of hilar lymph nodes examined: 2
- S. Extracapsular spread of hilar lymph node metastases: N/A
1. yes
2. no
- T. Mediastinal nodes involved: 2
1. yes
2. no
3. not applicable
- U. Mediastinal node group(s) involved (N2 nodes): # / # / # / # / # / #
1. Level 4R
2. Level 5R
3. Level 6R
4. Level 7R
5. Level 9R
6. Level 10R
7. Level 4L
8. Level 5L
9. Level 6L
10. Level 7L
11. Level 9L
12. Level 10L
- V. Number of positive mediastinal nodes: NA
- W. Total number of mediastinal nodes examined: 7
- X. Extracapsular spread of mediastinal lymph node metastases: NA
1. yes
2. No
- Y. Underlying disease(s): 1 / # / # / #
1. Emphysema
2. Bronchiectasis
3. Tumorlets
4. Smokers bronchiolitis
5. Asthma
6. Parenchymal scar
7. Pneumoconiosis, NOS
8. Chronic interstitial pneumonia
- Z. TNM Stage: T 1 N 1 M X

Source: NCI Genomic Data Commons file bd187f0f-cf7e-42ff-8c26-800d7fa3cae1 (TCGA-50-5932.D7713068-4D83-4242-BAE2-8035C1BA9B8D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).